Surgical pathology report (de-identified scan), TCGA case TCGA-96-8169, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - NYU, specimen TCGA-96-8169-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. RIGHT LOWER LOBE WEDGE RESECTION
2. STATION 9 LYMPH NODE
3. STATION 7 LYMPH NODE
4. STATION 4 LYMPH NODE

DIAGNOSIS:

1. **LUNG, RIGHT LOWER LOBE: WEDGE RESECTION**
- **SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED (1.6 CM), SEE NOTE.**
- **THE STAPLE LINE MARGIN IS FREE OF TUMOR.**

Note: Immunohistochemical stains show that the tumor cells are positive for p63 while negative for TTF-1, supporting the diagnosis. A mucin stain is negative.

2. **LYMPH NODE, LEVEL 9: BIOPSY**
- **ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).**
3. **LYMPH NODE, LEVEL 7: BIOPSY**
- **ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).**
4. **LYMPH NODE, LEVEL 4: BIOPSY**
- **TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).**

Specimens: 1: RIGHT LOWER LOBE WEDGE RESECTION
2: STATION 9 LYMPH NODE
3: STATION 7 LYMPH NODE
4: STATION 4 LYMPH NODE

LUNG: Resection
SPECIMEN

[page 2 of 4]
Specimen: Lung

Procedure: Wedge resection

Specimen Integrity: Intact

Specimen Laterality: Right

Tumor Site: Lower lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Squamous cell carcinoma

Histologic Grade: G3: Poorly differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

1.6cm

Visceral Pleura Invasion: Not identified

MARGINS

Parenchymal Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

LYMPH NODES

Extranodal Extension: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

4

Number Involved

0

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Emphysema

[REDACTED]

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

[REDACTED] ex-smoker with RLL NSCLC.

MACROSCOPIC DESCRIPTION:

The specimen is received in saline, in four parts, each labeled with the patient's name.

[page 3 of 4]
1. Part one is labeled 'right lower lobe wedge resection'. It consists of a wedge biopsy of the lung measuring 11 x 7 x 2.8 cm. The staple line measures 14 cm. The pleura are gray pink and glistening. There is a yellow tan sub pleural firm nodule with ill defined borders measuring 2 x 1.8 x 1.3 cm, located 1.6 cm from the staple line margin. The staple line is shaved and the pleura around the staple is inked blue. The pleural surface above the nodule is inked black. The remainder of the parenchyma is pink red blotchy and crepitant. No other nodule grossly identified. Representative sections are submitted.

2. Part two is labeled 'station #9 lymph node'. It consists of one soft red-black lymph node measuring 1 x 0.5 x 0.4 cm, which is bisected. Entirely submitted in one cassette.

3. Part three is labeled 'station #7 lymph node'. It consists of one soft red-black lymph node measuring 2.3 x 1 x 0.6 cm, which is bisected. Entirely submitted in one cassette.

4. Part four is labeled 'station #4 lymph node'. It consists of two soft red-black lymph nodes measuring 0.8 x 0.6 x 0.5 cm in aggregate. Entirely submitted in one cassette.

Duct/ [REDACTED] (part 1)
Dct/ [REDACTED] (parts 2-4)

SUMMARY OF SECTIONS:

1A-1D nodules
1E staple line margin
1F random section of parenchyma
2A in toto
3A in toto
4A in toto

SPECIAL PROCEDURES:

Mucin

This report may include one or more immunohistochemical stain

[page 4 of 4]
results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED] Department of Pathology.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file d988f962-2e1b-4435-8eaf-71dab75f6e9c (TCGA-96-8169.D0A4557A-FC0F-4B4E-BAE3-24B61F28719A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).